Surgical pathology report (de-identified scan), TCGA case TCGA-BA-5152, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-5152-01A (Primary Tumor).

[page 1 of 5]
Surgical Pathology Report

Diagnosis:

A: Right anterior muscle, removal

- No tumor seen.

B: Right middle muscle, removal

- No tumor seen.

C: Right lateral muscle, removal

- No tumor seen.

D: Right posterior mucosal margin, removal

- No tumor seen.

E: Right posterior middle margin, removal

- No tumor seen.

F: Right anterior mucosal margin, removal

- No tumor seen.

G: Right posterior deep margin, removal

- No tumor seen.

H: Right middle deep margin, removal

- No tumor seen.

I: Right anterior deep margin, removal

- No tumor seen.

J: Right anterior floor of mouth, removal

- Benign salivary gland tissue with focal atrophic changes, no tumor seen.

K: Right lateral floor of mouth, removal

- Benign salivary gland tissue with focal atrophic changes, no tumor seen.

L: Left neck, level 1, removal

- Benign adipose tissue, no tumor seen, no lymph node seen.

M: Lymph nodes, right neck level 1, removal

- No tumor seen in two lymph nodes (0/2).

N: Right neck, level 2 lymph nodes, removal

- No tumor seen in three lymph nodes (0/3).

- Submandibular gland present with no tumor seen.

O: Right neck, level 3 lymph nodes, removal

- No tumor seen in twelve lymph nodes (0/12).

P: Right mandible mass, removal

[page 2 of 5]
Histologic tumor type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Tumor arises in the gingiva overlying the mandible and invades into the bone of mandible

Presence/absence of CIS: not identified

Presence/absence of angiolymphatic space invasion: Not identified

Presence/absence of perineural space invasion: Not identified

Histologic assessment of surgical margins: Surgical margins free of tumor

Lymph nodes: See specimens L-0. All nodes free of tumor

Other significant findings: None

AJCC staging:

pT4

pN0

pMx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Intraoperative Consult Diagnosis:
requested a frozen section

FSA1: Right anterior muscle, removal
- No tumor seen

FSB1: Right middle muscle, removal
- No tumor seen

FSC1: Right lateral muscle, removal
- No tumor seen

FSD1: Right posterior mucosal margin, removal
- No tumor seen

FSE1: Right posterior middle margin, removal
- No tumor seen

FSF1: Right anterior mucosal margin, removal
- No tumor seen

FSG1: Right posterior deep margin, removal
- No tumor seen

FSH1: Right middle deep margin, removal
- No tumor seen

FSI1: Right anterior deep margin, removal

[page 3 of 5]
- No tumor seen

Frozen Section Pathologist:

Clinical History:

The patient is with a right oral cavity cancer.

Gross Description:

Received are eight appropriately labeled containers.

Specimen A is received fresh for frozen section and consists of a 0.7 x 0.6 x 0.3 cm red/tan soft tissue fragment, submitted in block FSA1, [REDACTED]

Specimen B is received fresh for frozen section and consists of a 1.5 x 1.1 x 0.5 cm red/tan soft tissue fragment, submitted in block FSB1, [REDACTED]

Specimen C is received fresh for frozen section and consists of a 1.0 x 0.9 x 0.7 cm red/tan soft tissue fragment, submitted in block FSC1, [REDACTED]

Specimen D is received fresh for frozen section and consists of a 1.1 x 0.6 x 0.4 cm red/tan soft tissue fragment, submitted in block FSD1, [REDACTED]

Specimen E is received fresh for frozen section and consists of a 1.1 x 0.6 x 0.4 cm red/tan soft tissue fragment, submitted in block FSE1, [REDACTED]

Specimen F is received fresh for frozen section and consists of a 0.3 x 0.3 x 0.2 cm red/tan soft tissue fragment, submitted in block FSF1, [REDACTED]

Specimen G is received fresh for frozen section and consists of a 0.3 x 0.2 x 0.2 cm red/tan soft tissue fragment, submitted in block FSG1, [REDACTED]

Specimen H is received fresh for frozen section and consists of a 0.6 x 0.5 x 0.3 cm red/tan soft tissue fragment, submitted in block FSH1, [REDACTED]

Specimen I is received fresh for frozen section and consists of a 0.6 x 0.4 x 0.4 cm red/tan soft tissue fragment, submitted in block FSI, [REDACTED]

Specimen J is received in an appropriately labeled formalin-filled container, additionally labeled "further anterior floor of mouth" and holds one fibrofatty piece of tissue that measures 2.0 x 1.3 x 0.5 cm. The specimen was submitted in to block J1, [REDACTED]

Specimen K is received in an appropriately labeled formalin-filled container, additionally labeled "right lateral floor of mouth" and holds one fibrofatty piece of tissue that measures 1.5 x 0.9 x 0.7 cm. The specimen was bisected and submitted in to block K1, [REDACTED]

Specimen L is received in an appropriately labeled formalin-filled container, additionally labeled "left level one" and holds one fibrofatty piece of tissue that measures 1.5 x 1.4 x 1.2 cm. The specimen was bisected and submitted in to block L1, [REDACTED]

Specimen M is received in an appropriately labeled formalin-filled container, additionally labeled "right level one" and holds one fibrofatty piece of tissue that measures 5.0 x 3.5 x 1.5 cm. Two lymph nodes are identified with the largest one measuring 1.4 x 0.8 x 0.5cm.

Block Summary:

M1 - Largest lymph node, bisected

M2 - Lymph node #2, bisected

[page 4 of 5]
M3-M7 - Remainder of associated adipose tissue in specimen, [REDACTED]

Specimen N is received in an appropriately labeled formalin-filled container, additionally labeled "right level two" and holds one fibrofatty piece of tissue that measures 4.0 x 3.3 x 2.5 cm. There is an associated salivary gland within the mass of tissue that measures 3.2 x 3.0 x 1.5 cm. Three candidate lymph nodes are identified with the largest measuring 1.2 x 0.6 x 0.8 cm.

Block Summary:

N1 - Largest lymph node, bisected

N2 - Lymph node #2, bisected

N3 - Lymph node, not bisected

N4-N6 - Remainder of associated fatty tissue surrounding lymph nodes

N7 - Representative section of salivary gland present

Specimen O is received in an appropriately labeled formalin-filled container, additionally labeled "right level three" and holds one fibrofatty piece of tissue that measures 5.0 x 4.5 x 2.5 cm. Six candidate lymph nodes are identified with the largest measuring 2.0 x 1.0 x 1.0 cm.

Block Summary:

O1 - Largest lymph node, bisected

O2-O4 - One lymph node per cassette, bisected

O5 - Two lymph nodes, not bisected

O6-O18 - Remainder of fatty tissue associated with lymph nodes

Specimen P:

Specimen fixation: Formalin

Type of specimen: Right mandible, partial resection

Size of specimen: 5.3 x 4.4 x 1.7 cm

Orientation of specimen: Anterior/yellow, lateral/black, posterior/red, medial/blue.

Tumor description: There is an ulcerative lesion occurring around the third incisor that is displacing the third incisor in the third incisor is the anterior to lateral direction. The tumor appears ulcerative and tan/gray in color.

Location of tumor: On the lower alveolus and gingival gum; the tumor does extend down into the mandible.

Tumor size: 2.5 cm x 1.0 cm x 1.3 cm

Extent of tumor: The tumor involves the mandibular bone and the adjacent soft tissue.

Presence/absence of bone involvement: Yes, the tumor does involve the mandible.

Distance of tumor from surgical margins: Mucosal margins: tumor is 1.6 cm away from the lateral/posterior margin, 1.1 cm away from the lateral/anterior margin, 0.4 cm away from the medial/anterior margin and 2.3 cm away from the medial/posterior margin. On cut margins, the tumor is 3 mm to the black ink (lateral margin) and 4 mm to the blue ink (medial margin).

Description of remainder of tissue: The remaining bone appears tan/yellow in color with no other focal lesions or masses.

Tissue submitted for special investigations: No

[page 5 of 5]
Lymph nodes: Not given

Digital photograph taken: No

Block Summary:

Inking: anterior/yellow, posterior/red, medial/blue and lateral/black

P1 - En face, anterior margin

P2 - En face, posterior margin

P3-P4 - Deepest margin, perpendicular section

Grossing Pathologist:

Light Microscopy:

Light microscopic examination is performed

Signature

Resident Physician:

Attending Pathologist: I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 67b6c088-6c5b-40b9-88c5-74287dd2dbbb (TCGA-BA-5152.B8DDAB17-48AE-4286-BCE7-1C6FBBA62DAC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).